FM case AD3358 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/135fecab-f681-4dea-94a8-c2cb6d74224f

Female, 51.7 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the endometrium. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
